Gene-level copy-number profile of tumor specimen TCGA-E7-A8O8-01A from TCGA case TCGA-E7-A8O8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.2 years (21,629 days).
Specimen TCGA-E7-A8O8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a063b08c-7c1c-46ed-b360-feaa973f78eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A8O8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate.
https://portal.gdc.cancer.gov/files/54a61e59-06cd-44a9-a540-cec7fb542a88

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,027; copy number 2: 43,795; copy number 3: 6,465; copy number 4: 400; copy number 5: 128.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 128 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:23,685,400–26,477,840, 126 genes, copy number 5 (broad region; genes not listed).
- chr15:26,557,598–26,658,763, 2 genes, copy number 5: AC009878.1, AC011196.1.

Autosomal genes at a single copy (total copy number 1): 6,606. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
